Somatic mutation profile of tumor specimen TCGA-V4-A9F4-01A (aliquot TCGA-V4-A9F4-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F4, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 42.0 years (15,332 days).
Specimen TCGA-V4-A9F4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84b9e90d-ecd0-40c5-a44b-a4a0ffd5c972.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F4-10A (Blood Derived Normal), aliquot TCGA-V4-A9F4-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89412658-40dd-4888-aa30-ea951937a19d

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 38/85 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALYREF | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs866240403; called by muse, mutect2
- EVC | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs201583621, COSV53833359; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EYA3 | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1367960963; called by muse, mutect2, varscan2
- MUCL3 | c.1130C>G p.S377C (on ENST00000304311; = p.S1253C on NM_080870.4) | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1347896822, COSV100423891; called by muse, mutect2, varscan2
- MUCL3 | c.1233C>G p.I411M (on ENST00000304311; = p.I1287M on NM_080870.4) | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as rs751853704; called by muse, mutect2, varscan2
- NEDD4 | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs148700559; called by muse, mutect2, varscan2
- USP35 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1273026171, COSV71572701; called by muse, mutect2, varscan2
- ZNF195 | c.1576G>A p.E526K (on ENST00000399602 / NM_001130520.3; = p.E454K on NM_007152.5) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs376637698; called by muse, mutect2, varscan2
- CNTN3 | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FANCM | c.5881G>T p.V1961F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MUCL3 | c.1026C>G p.T342= (on ENST00000304311; = p.T1218= on NM_080870.4) | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, varscan2
